Somatic mutation profile of tumor specimen TCGA-ZP-A9D0-01A (aliquot TCGA-ZP-A9D0-01A-11D-A36X-10) from TCGA case TCGA-ZP-A9D0, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G1; Age at diagnosis: 67.1 years (24,525 days).
Specimen TCGA-ZP-A9D0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7c81e0a-0e50-43d3-8237-99f1fc5d1da3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZP-A9D0-10A (Blood Derived Normal), aliquot TCGA-ZP-A9D0-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cf494eb-6c14-40ba-8c67-92688e12a9ba

The open-access MAF lists 64 somatic variants for this specimen: 46 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 16, Frame Shift Del 4, Nonsense Mutation 2, Intron 1, RNA 1, Frame Shift Ins 1, In Frame Del 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAP3 | c.2365C>T p.R789C | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100330328; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5479C>T p.P1827S | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV99784842; called by muse, mutect2, varscan2
- ANKRD26 | c.4071_4074del p.E1359* | Frame Shift Del (DEL) | VAF 91/254 reads (36%) | catalogued as rs762341895; called by mutect2, pindel, varscan2
- B4GALT7 | c.908G>A p.G303D | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99219151; called by muse, mutect2, varscan2
- CCAR1 | c.57_58insA p.A20Sfs*74 | Frame Shift Ins (INS) | VAF 29/98 reads (30%) | catalogued as COSV99771516; called by mutect2, pindel, varscan2
- CEP135 | c.2259G>T p.L753F | Missense Mutation (SNP) | VAF 151/452 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.946); catalogued as COSV99954990; called by muse, mutect2, varscan2
- CKM | c.832G>C p.G278R | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99489001; called by muse, mutect2, varscan2
- CLDN5 | c.320G>A p.C107Y (on ENST00000618236 / NM_001363066.2; = p.C192Y on NM_003277.4) | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99597134; called by muse, mutect2, varscan2
- CNTNAP5 | c.3160C>T p.L1054F | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.192); catalogued as COSV101443140, COSV70475536; called by muse, mutect2, varscan2
- DOCK5 | c.4076A>G p.Q1359R | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV99378350; called by muse, mutect2, varscan2
- ERGIC1 | c.562A>C p.I188L | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.081); catalogued as rs140909162; called by muse, mutect2, varscan2
- FOXL2 | c.655C>G p.Q219E | Missense Mutation (SNP) | VAF 170/415 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as CM010306, COSV57725843, COSV57730563; called by muse, mutect2, varscan2
- FSIP2 | c.16208C>T p.S5403F | Missense Mutation (SNP) | VAF 84/228 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.692); catalogued as COSV100556909; called by muse, mutect2, varscan2
- FTMT | c.161C>A p.S54Y | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.089); catalogued as COSV100360498, COSV58420205; called by muse, mutect2, varscan2
- GRM5 | c.3256A>T p.S1086C (on ENST00000305447 / NM_001143831.2; = p.S1054C on NM_000842.4) | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.221); catalogued as COSV100555034; called by muse, mutect2, varscan2
- HMGB1 | c.320C>G p.S107C | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as COSV100361051, COSV58105504; called by muse, mutect2, varscan2
- HSPA12B | c.230G>C p.S77T | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV99654283; called by muse, mutect2, varscan2
- IFI35 | c.745G>C p.D249H (on ENST00000415816 / NM_001330230.2; = p.D251H on NM_005533.5) | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55895992, COSV99887977; called by muse, mutect2, varscan2
- MFAP5 | c.484T>A p.C162S | Missense Mutation (SNP) | VAF 86/264 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100848203; called by muse, varscan2
- NRXN3 | c.912A>G p.P304= (on ENST00000557594 / NM_001272020.2; = p.P936= on NM_004796.6) | Splice Region (SNP) | VAF 24/55 reads (44%) | catalogued as COSV99822749; called by muse, mutect2, varscan2
- PRKAG2 | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV99836324; called by muse, mutect2, varscan2
- PRPF8 | c.3232G>A p.A1078T | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV59262114; called by muse, mutect2, varscan2
- PRUNE2 | c.7496A>C p.D2499A | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.939); catalogued as COSV100945320; called by muse, mutect2, varscan2
- RASA1 | c.1771C>G p.R591G | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV57194722, COSV99171476; called by muse, mutect2, varscan2
- REXO4 | c.1162C>T p.Q388* | Nonsense Mutation (SNP) | VAF 15/24 reads (63%) | catalogued as rs1554779024, COSV100905735, COSV100905787; called by muse, mutect2, varscan2
- RFESD | c.434A>T p.Y145F | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.09); catalogued as COSV99174202; called by muse, mutect2, varscan2
- SLC5A12 | c.728T>A p.V243E | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV54819343; called by muse, mutect2, varscan2
- SLFN11 | c.1888G>A p.V630I | Missense Mutation (SNP) | VAF 82/439 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs765053182, COSV100391125; called by muse, mutect2, varscan2
- SLFN13 | c.1888G>A p.V630I | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs537700636; called by mutect2, varscan2
- SMAP2 | c.827C>T p.T276M | Missense Mutation (SNP) | VAF 43/63 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs202167503, COSV65531225; called by muse, mutect2, varscan2
- STX6 | c.14A>T p.D5V | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99276208; called by muse, mutect2, varscan2
- SVEP1 | c.7493G>A p.C2498Y | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99930093; called by muse, mutect2, varscan2
- SYNE2 | c.14560C>A p.L4854M | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100648633; called by muse, mutect2, varscan2
- TAB3 | c.196A>T p.M66L | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as COSV99916961; called by muse, mutect2, varscan2
- TOGARAM2 | c.291G>C p.L97F | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.797); catalogued as COSV101091295, COSV101091589; called by muse, mutect2, varscan2
- TPT1 | c.29A>T p.H10L | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV100496042; called by muse, mutect2, varscan2
- UTP20 | c.8284G>C p.E2762Q | Missense Mutation (SNP) | VAF 117/328 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.916); catalogued as COSV55371803; called by muse, mutect2, varscan2
- ZHX1 | c.1810C>G p.Q604E | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99933950; called by muse, mutect2, varscan2
- ZNF681 | c.129G>T p.L43F | Missense Mutation (SNP) | VAF 159/503 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68076099; called by muse, mutect2, varscan2
- ZSCAN30 | c.1340G>C p.G447A | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV99735244; called by muse, mutect2, varscan2
- ATP2A2 | c.2539_2553del p.T847_A851del | In Frame Del (DEL) | VAF 21/84 reads (25%) | called by mutect2, pindel, varscan2
- CASS4 | c.577del p.Q193Sfs*28 | Frame Shift Del (DEL) | VAF 37/112 reads (33%) | called by mutect2, pindel, varscan2
- IFIT3 | c.1454del p.N485Tfs*5 | Frame Shift Del (DEL) | VAF 27/89 reads (30%) | called by mutect2, pindel, varscan2
- NOS3 | c.3186_3193del p.N1063Afs*17 | Frame Shift Del (DEL) | VAF 19/55 reads (35%) | called by mutect2, pindel, varscan2
- PRAMEF10 | c.450C>A p.F150L | Missense Mutation (SNP) | VAF 59/274 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PRSS21 | c.92-8_103del p.X31_splice | Splice Site (DEL) | VAF 18/80 reads (23%) | called by mutect2, pindel, varscan2
- AHCTF1 | c.3879T>G p.P1293= (on ENST00000366508; = p.P1267= on NM_015446.5) | Silent (SNP) | VAF 158/359 reads (44%) | catalogued as COSV100404622; called by muse, mutect2, varscan2
- ANK3 | c.8613G>T p.S2871= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as rs754091164, COSV99783049; called by muse, mutect2, varscan2
- ARPC5 | c.165A>G p.L55= | Silent (SNP) | VAF 35/205 reads (17%) | catalogued as COSV99665002; called by muse, mutect2, varscan2
- AXIN2 | c.1512C>G p.G504= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV100197086, COSV61056445; called by muse, mutect2, varscan2
- CR1 | c.3111C>T p.L1037= | Silent (SNP) | VAF 90/446 reads (20%) | catalogued as rs746948411, COSV100887783, COSV65465875; called by muse, mutect2, varscan2
- GALNT10 | c.153G>A p.A51= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV99770136; called by muse, mutect2, varscan2
- GRAMD4 | c.630C>T p.R210= | Silent (SNP) | VAF 42/114 reads (37%) | catalogued as rs202227527, COSV63029184; called by muse, mutect2, varscan2
- HSF2 | c.1134A>G p.L378= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as rs201391717, COSV100869758; called by muse, mutect2, varscan2
- NECTIN3 | c.591T>G p.T197= | Silent (SNP) | VAF 69/186 reads (37%) | catalogued as COSV100162831; called by muse, mutect2, varscan2
- PCDHGA11 | c.489G>A p.V163= | Silent (SNP) | VAF 34/122 reads (28%) | catalogued as COSV99549427; called by muse, mutect2
- PREX1 | c.3336G>A p.S1112= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as rs764777154, COSV100906921; called by muse, mutect2, varscan2
- RNF128 | c.166T>C p.L56= | Silent (SNP) | VAF 12/417 reads (3%) | called by muse, mutect2
- SCN1A | c.4524T>C p.Y1508= (on ENST00000303395 / NM_001202435.3; = p.Y1497= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/146 reads (37%) | catalogued as rs778620898, CM113341, COSV100322620; called by muse, mutect2, varscan2
- SFXN5 | c.273G>A p.K91= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV99730153; called by muse, mutect2, varscan2
- STAG2 | c.1806T>C p.T602= | Silent (SNP) | VAF 120/379 reads (32%) | catalogued as COSV99495799; called by muse, mutect2, varscan2
- TNFRSF18 | c.285C>G p.P95= | Silent (SNP) | VAF 104/303 reads (34%) | catalogued as COSV100149006, COSV60775933; called by muse, mutect2, varscan2
- AGAP7P | n.838C>T | RNA (SNP) | VAF 12/45 reads (27%) | catalogued as rs1554941059; called by muse, mutect2, varscan2
- PITX2 | c.185-909C>A | Intron (SNP) | VAF 72/158 reads (46%) | catalogued as COSV100146556; called by muse, mutect2, varscan2
